TCGA case TCGA-FE-A234 — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: Ohio State University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e4c85bdd-7b7c-414f-9503-647d9b825915

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 26 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 26.6 years (9,724 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,075 days (5.7 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 2; Measurement unit: Centimeters; Tumor depth measurement: 2.5; Tumor length measurement: 3.3; Tumor width measurement: 3.
   Treatment given: Treatment type: Radiation, Radioisotope; Treatment intent type: Adjuvant; Days to treatment start: 106 days; Days to treatment end: 106 days; Treatment dose: 152 mCi; Course number: 1; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 152; Prescribed dose units: mCi; Pretreatment: Thyroxine Withdrawal; Timepoint category: First Treatment.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 152 mCi; Pretreatment: Thyroxine Withdrawal.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Papillary adenocarcinoma, NOS), site: Lymph node, NOS. Age at diagnosis: 27.9 years (10,207 days); Days to diagnosis: 483 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 483 days (1.3 years).
   Recorded as not given: I-131 Radiation Therapy, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (6 entries)
- Day 483 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 483 days (1.3 years); Evidence of recurrence type: Histologic Confirmation; Histologic progression: No.
- Days to follow up: 1,333 days (3.6 years); Disease response: With Tumor.
- Days to follow up: 1,697 days (4.6 years); Disease response: With Tumor.
- Days to follow up: 2,075 days (5.7 years); Disease response: With Tumor.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.
- Imaging anatomic site: Lymph Node; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FE-A234-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 130 mg.
  Slide TCGA-FE-A234-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FE-A234-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FE-A234-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Right lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Genotypic analysis detected: No.
- Follow-up form 1: I 131 radiation first treatment dose: 152 mCi; I 131 radiation treatment cumulative dose: 152 mCi; Radiation therapy xrt method prep: Patient Did Not Receive Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease; Tumor status: With tumor.
- Follow-up form 1, New tumor: New tumor event diagnosis confirmed by: Pathology; New tumor event histo progression: No; New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node Only; New tumor event node site: Central (levels 6-7); New tumor event treatment: Surgery (distant metastasis); New tumor event surgery: Yes; I 131 radiation first treatment method: Patient did not receive I-131 treatment; Radiation therapy xrt method prep: Patient Did Not Receive Radiation Therapy; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,075 days; disease-specific survival: no event (censored), 2,075 days; disease-free interval: event (new tumor event after initially disease-free), 483 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 483 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FE-A234-01A-11D-A14V-01): tumor purity 0.58, ploidy 2, whole-genome doublings 0.
